Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041117-09A.2 (aliquot TARGET-15-SJMPAL041117-09A.2-01D) from TARGET case TARGET-15-SJMPAL041117, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.1 years (5,523 days).
Specimen TARGET-15-SJMPAL041117-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 201cd6af-45c9-4de9-ab6f-9cd7f6a07351.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041117-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041117-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18182588-2aca-445b-b4b9-d14906e48278

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 5, Intron 3, In Frame Del 2, In Frame Ins 2, Frame Shift Ins 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 83/210 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13361G>A p.R4454H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1280212847, COSV68946313; called by muse, mutect2
- C6 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs756691542, COSV54705309; called by muse, mutect2, varscan2
- CADM3 | c.541G>A p.E181K (on ENST00000368125 / NM_001127173.3; = p.E215K on NM_021189.5) | Missense Mutation (SNP) | VAF 42/62 reads (68%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as rs1325982988; called by muse, mutect2, varscan2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2, varscan2
- FAM47A | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60500739; called by muse, mutect2, varscan2
- HRNR | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 111/442 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs369964728; called by muse, mutect2, varscan2
- IKBKE | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782392890; called by muse, mutect2, varscan2
- PCDHA1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.052); catalogued as rs1446677911, COSV65374909; called by muse, mutect2, varscan2
- PCDHGA2 | c.2128G>A p.V710M | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.133); catalogued as COSV99541963; called by muse, mutect2, varscan2
- RB1CC1 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs769839464; called by muse, mutect2, varscan2
- THBS4 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as rs376939207; called by muse, mutect2, varscan2
- XIRP2 | c.7900G>A p.G2634R (on ENST00000628543; = p.G2809R on NM_152381.6) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1412549174, COSV54704403, COSV99741308; called by muse, mutect2
- ANKRD40 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.101); called by muse, varscan2
- COPB2 | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CREBBP | c.3838_3839insGGGGG p.F1280Wfs*35 | Frame Shift Ins (INS) | VAF 54/167 reads (32%) | called by mutect2, pindel, varscan2
- FAM81A | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- FBN3 | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA0825 | c.2394_2398delinsCCGAC p.Q798_K800delinsHRQ | Missense Mutation (ONP) | VAF 14/43 reads (33%) | called by pindel, varscan2*
- MAPK7 | c.900C>A p.S300R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- MRPL39 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NSD3 | c.507_508insATGAG p.S170Mfs*10 | Frame Shift Ins (INS) | VAF 32/72 reads (44%) | called by mutect2, varscan2
- POU4F1 | c.963_964insTCTTCC p.N321_M322insSS | In Frame Ins (INS) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- PRPF40A | c.1475_1477del p.E492del | In Frame Del (DEL) | VAF 11/40 reads (28%) | called by pindel, varscan2
- SLC2A3 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBC1D23 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TPPP | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSC22D2 | c.1630_1631insCCCCAAGCC p.S543_H544insPPS | In Frame Ins (INS) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- TTLL3 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.597); called by mutect2, varscan2
- VPS13C | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- WDFY3 | c.7555_7557del p.E2519del | In Frame Del (DEL) | VAF 18/84 reads (21%) | called by pindel, varscan2
- ADGRL3 | c.1437G>A p.P479= (on ENST00000506720 / NM_001322402.2; = p.P411= on NM_015236.6) | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs147936284; called by muse, mutect2, varscan2
- ATP7B | c.1830G>A p.P610= | Silent (SNP) | VAF 56/159 reads (35%) | catalogued as rs375689672; ClinVar: likely benign; called by muse, mutect2, varscan2
- BPIFB4 | c.378C>T p.A126= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as rs772687337, COSV64951085; called by muse, mutect2, varscan2
- MYO15B | c.7245C>T p.D2415= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1240821087; called by muse, mutect2, varscan2
- ZNF131 | c.612T>C p.G204= | Silent (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- ATG4D | c.236-17C>T | Intron (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576542 C>T | 5'Flank (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- NOL3 | c.*64C>A | 3'UTR (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- RAP1GAP | c.-148-1625G>T | Intron (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- RIMS1 | c.1679-20566C>T | Intron (SNP) | VAF 13/57 reads (23%) | catalogued as rs1348116165; called by muse, mutect2, varscan2
